Somatic mutation profile of tumor specimen TCGA-76-4925-01A (aliquot TCGA-76-4925-01A-01D-1486-08) from TCGA case TCGA-76-4925, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 76.7 years (28,011 days).
Specimen TCGA-76-4925-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 61d80f19-83a9-4dec-af2b-82b2c8b53fd3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-76-4925-10A (Blood Derived Normal), aliquot TCGA-76-4925-10A-01D-1486-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ffa4c2fc-7937-4a47-a622-e88e90683055

The open-access MAF lists 72 somatic variants for this specimen: 52 protein-altering or splice-affecting, 18 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 44, Silent 18, Splice Site 3, Frame Shift Del 2, Frame Shift Ins 2, Intron 1, Nonsense Mutation 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PTEN | c.741dup p.P248Tfs*5 | Frame Shift Ins (INS) | VAF 76/118 reads (64%) | catalogued as rs587782341, CI043805, COSV64288762; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- THSD7B | c.1670G>T p.G557V | Missense Mutation (SNP) | VAF 53/104 reads (51%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV55689123, COSV55699747; called by muse, mutect2, varscan2
- TP53 | c.746G>C p.R249T | Missense Mutation (SNP) | VAF 36/53 reads (68%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs587782329, COSV52666526, COSV52668050, COSV52697169, COSV52713804; ClinVar: not provided / likely pathogenic; called by muse, mutect2, varscan2
- ARHGAP39 | c.1381C>T p.P461S | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT tolerated (0.5); PolyPhen benign (0.229); catalogued as COSV99431234; called by muse, mutect2, varscan2
- ARMCX5-GPRASP2 | c.482C>T p.P161L | Missense Mutation (SNP) | VAF 177/192 reads (92%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as COSV63438227; called by muse, varscan2
- CALCA | c.136G>A p.E46K | Missense Mutation (SNP) | VAF 61/115 reads (53%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.88); catalogued as rs782339903, COSV59027618; called by muse, mutect2, varscan2
- CALCR | c.557A>G p.Y186C | Missense Mutation (SNP) | VAF 3/17 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.003); catalogued as COSV64009054; called by muse, mutect2
- CASZ1 | c.4502G>A p.C1501Y | Missense Mutation (SNP) | VAF 9/15 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV65458675; called by muse, mutect2, varscan2
- CLEC4C | c.79G>A p.V27I | Missense Mutation (SNP) | VAF 62/135 reads (46%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs370896266; called by muse, mutect2, varscan2
- CLUAP1 | c.70A>G p.M24V | Missense Mutation (SNP) | VAF 95/104 reads (91%) | SIFT tolerated (0.08); PolyPhen benign (0.268); catalogued as rs760629659, COSV58893966; called by muse, mutect2, varscan2
- COPG1 | c.1142A>G p.Q381R | Missense Mutation (SNP) | VAF 54/134 reads (40%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.954); catalogued as COSV59114631; called by muse, mutect2, varscan2
- CRACDL | c.2668G>A p.A890T | Missense Mutation (SNP) | VAF 181/411 reads (44%) | SIFT tolerated (0.51); PolyPhen benign (0.003); catalogued as rs750928579, COSV67408641; called by muse, mutect2, varscan2
- CREB3L3 | c.767C>T p.S256L | Missense Mutation (SNP) | VAF 27/81 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs147422200; called by muse, mutect2, varscan2
- CYLC2 | c.46A>T p.N16Y | Missense Mutation (SNP) | VAF 38/86 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV66337998; called by muse, mutect2, varscan2
- DDX5 | c.440_441+2del p.X147_splice | Splice Site (DEL) | VAF 113/320 reads (35%) | catalogued as rs782442161; called by mutect2, pindel, varscan2
- DENND4C | c.1314G>A p.M438I | Missense Mutation (SNP) | VAF 158/190 reads (83%) | SIFT deleterious (0); PolyPhen benign (0.364); catalogued as COSV66822406; called by muse, mutect2, varscan2
- DNAH11 | c.1466G>A p.R489K | Missense Mutation (SNP) | VAF 33/117 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV60961299; called by muse, mutect2, varscan2
- DPYD | c.1945G>T p.D649Y | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64596537, COSV64601580; called by muse, mutect2, varscan2
- EIF3H | c.217G>A p.E73K | Missense Mutation (SNP) | VAF 51/129 reads (40%) | SIFT tolerated (0.09); PolyPhen benign (0.096); catalogued as COSV52667513, COSV52668000; called by muse, mutect2, varscan2
- FAM83H | c.2732G>A p.R911H | Missense Mutation (SNP) | VAF 22/43 reads (51%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as rs1554622033, COSV62028795, COSV62028918; called by muse, mutect2, varscan2
- GATA6 | c.1478G>A p.R493Q | Missense Mutation (SNP) | VAF 27/90 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV52524873; called by muse, mutect2, varscan2
- HECTD4 | c.12305A>T p.K4102M | Missense Mutation (SNP) | VAF 10/152 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.601); catalogued as COSV66393849; called by muse, mutect2
- HFM1 | c.3685A>G p.I1229V | Missense Mutation (SNP) | VAF 56/119 reads (47%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0.015); catalogued as rs1449312754, COSV54029651; called by muse, mutect2, varscan2
- IL16 | c.3629C>G p.T1210S (on ENST00000302987 / NM_172217.5; = p.T509S on NM_004513.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 98/209 reads (47%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as COSV57155147; called by muse, mutect2, varscan2
- INO80B | c.699G>T p.E233D | Missense Mutation (SNP) | VAF 6/9 reads (67%) | SIFT deleterious (0.02); PolyPhen benign (0.097); catalogued as rs761831658; called by muse, varscan2
- IQSEC3 | c.1045C>T p.R349W (on ENST00000538872 / NM_001170738.2; = p.R46W on NM_015232.1) | Missense Mutation (SNP) | VAF 20/34 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58286189; called by muse, mutect2
- LAMTOR3 | c.238-2A>C p.X80_splice | Splice Site (SNP) | VAF 33/77 reads (43%) | catalogued as COSV56952361; called by muse, mutect2, varscan2
- MCOLN3 | c.1061T>C p.I354T | Missense Mutation (SNP) | VAF 22/43 reads (51%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as rs1040727519, COSV62014663; called by muse, mutect2, varscan2
- MED12L | c.1745C>T p.P582L | Missense Mutation (SNP) | VAF 126/291 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56382902; called by muse, mutect2, varscan2
- MMP13 | c.674G>A p.G225D | Missense Mutation (SNP) | VAF 130/317 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52823551, COSV52824383; called by muse, mutect2, varscan2
- MTA2 | c.785G>A p.R262Q | Missense Mutation (SNP) | VAF 79/182 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as rs1344596259, COSV53872632; called by muse, mutect2, varscan2
- MTMR12 | c.714-2A>G p.X238_splice | Splice Site (SNP) | VAF 11/32 reads (34%) | catalogued as COSV53785256; called by muse, mutect2, varscan2
- NDUFA4 | c.24G>C p.Q8H | Missense Mutation (SNP) | VAF 131/618 reads (21%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as COSV60012154; called by muse, mutect2, varscan2
- OR8K3 | c.334del p.L112Ffs*23 | Frame Shift Del (DEL) | VAF 62/180 reads (34%) | catalogued as rs773811085, COSV57132437, COSV57133525; called by mutect2, pindel, varscan2
- POLE2 | c.1141C>T p.L381F | Missense Mutation (SNP) | VAF 43/90 reads (48%) | SIFT deleterious (0.01); PolyPhen benign (0.031); catalogued as rs754195790, COSV53560410; called by muse, mutect2, varscan2
- PROKR2 | c.491G>A p.R164Q | Missense Mutation (SNP) | VAF 129/434 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs751875578, CM065402, COSV54087267, COSV54087377; called by muse, mutect2, varscan2
- RAVER1 | c.880G>A p.V294I | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT tolerated (0.23); PolyPhen benign (0.001); catalogued as COSV53346209; called by muse, mutect2, varscan2
- RORC | c.683G>A p.R228Q | Missense Mutation (SNP) | VAF 42/106 reads (40%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs200978307, COSV59093609; called by muse, mutect2, varscan2
- SF1 | c.389A>G p.K130R | Missense Mutation (SNP) | VAF 145/321 reads (45%) | SIFT tolerated (0.56); PolyPhen benign (0.174); catalogued as COSV57115076; called by muse, mutect2, varscan2
- SLCO6A1 | c.509A>T p.K170I | Missense Mutation (SNP) | VAF 85/187 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0.027); catalogued as COSV65811051; called by muse, mutect2, varscan2
- STXBP5 | c.3334G>C p.G1112R (on ENST00000321680 / NM_001127715.2; = p.G1076R on NM_139244.4) | Missense Mutation (SNP) | VAF 80/202 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51653689; called by muse, mutect2, varscan2
- SUCLG1 | c.133G>A p.A45T | Missense Mutation (SNP) | VAF 48/121 reads (40%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.022); catalogued as COSV67265313; called by muse, mutect2, varscan2
- SYT13 | c.794C>T p.T265I | Missense Mutation (SNP) | VAF 126/262 reads (48%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as COSV50074282; called by muse, mutect2, varscan2
- TCN1 | c.490G>A p.A164T | Missense Mutation (SNP) | VAF 119/267 reads (45%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs77116206, COSV57253579; called by muse, mutect2, varscan2
- TFAP2C | c.516C>A p.H172Q | Missense Mutation (SNP) | VAF 17/52 reads (33%) | SIFT tolerated (0.14); PolyPhen benign (0.001); catalogued as COSV52371879; called by muse, mutect2, varscan2
- TRPV5 | c.904C>T p.R302* | Nonsense Mutation (SNP) | VAF 75/234 reads (32%) | catalogued as rs1202128892, COSV54683675, COSV54686970; called by muse, mutect2, varscan2
- USP35 | c.2728A>C p.T910P | Missense Mutation (SNP) | VAF 173/345 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60868705; called by muse, mutect2, varscan2
- ZFP57 | c.817G>C p.E273Q | Missense Mutation (SNP) | VAF 89/215 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.714); catalogued as COSV65306338; called by muse, mutect2, varscan2
- ZIC1 | c.187G>A p.A63T | Missense Mutation (SNP) | VAF 44/83 reads (53%) | SIFT tolerated (0.11); PolyPhen benign (0.175); catalogued as rs745325418, COSV51551025, COSV51554717; called by muse, mutect2, varscan2
- ZMIZ1 | c.901G>A p.A301T | Missense Mutation (SNP) | VAF 68/81 reads (84%) | SIFT tolerated, low confidence (0.05); PolyPhen possibly damaging (0.824); catalogued as COSV57892061; called by muse, mutect2, varscan2
- CFAP221 | c.1074_1077dup p.F360Tfs*3 | Frame Shift Ins (INS) | VAF 54/151 reads (36%) | called by mutect2, pindel, varscan2
- NCDN | c.678_681del p.S226Rfs*47 | Frame Shift Del (DEL) | VAF 48/154 reads (31%) | called by mutect2, pindel, varscan2
- AC004593.2 | c.1047G>A p.V349= | Silent (SNP) | VAF 45/165 reads (27%) | catalogued as COSV56094622; called by muse, mutect2, varscan2
- ADAMTS9 | c.5325C>T p.P1775= | Silent (SNP) | VAF 158/355 reads (45%) | catalogued as COSV55783428; called by muse, mutect2, varscan2
- CD300A | c.75G>A p.A25= | Silent (SNP) | VAF 110/244 reads (45%) | catalogued as rs771248555, COSV60411342; called by mutect2, varscan2
- CNTN3 | c.2631G>A p.T877= | Silent (SNP) | VAF 203/418 reads (49%) | catalogued as rs750002537, COSV55174636; called by muse, mutect2, varscan2
- ELN | c.1410G>A p.Q470= | Silent (SNP) | VAF 42/142 reads (30%) | catalogued as COSV52711543; called by muse, mutect2, varscan2
- ENG | c.174C>T p.P58= | Silent (SNP) | VAF 208/435 reads (48%) | catalogued as COSV61227781; called by muse, mutect2, varscan2
- GRM8 | c.399T>C p.C133= | Silent (SNP) | VAF 67/245 reads (27%) | catalogued as COSV58835342; called by muse, mutect2, varscan2
- KLK5 | c.138C>T p.S46= | Silent (SNP) | VAF 33/40 reads (83%) | catalogued as COSV60450615; called by muse, mutect2, varscan2
- MMRN2 | c.993C>T p.A331= | Silent (SNP) | VAF 72/82 reads (88%) | catalogued as rs200423909, COSV64400867; called by muse, mutect2, varscan2
- NTRK1 | c.2175G>A p.K725= | Silent (SNP) | VAF 98/243 reads (40%) | catalogued as COSV62326272; called by muse, mutect2, varscan2
- OR10A3 | c.114C>T p.T38= | Silent (SNP) | VAF 68/175 reads (39%) | catalogued as COSV62459676; called by muse, mutect2, varscan2
- PCDHA3 | c.2190C>T p.G730= | Silent (SNP) | VAF 141/312 reads (45%) | catalogued as COSV63542786; called by muse, mutect2, varscan2
- PLCG2 | c.408G>A p.A136= | Silent (SNP) | VAF 129/307 reads (42%) | catalogued as rs747155855, COSV63870280; called by muse, mutect2, varscan2
- PLEKHG2 | c.984C>G p.P328= | Silent (SNP) | VAF 10/12 reads (83%) | catalogued as COSV52685291; called by muse, mutect2
- POPDC2 | c.576G>A p.Q192= | Silent (SNP) | VAF 76/201 reads (38%) | catalogued as COSV51741591; called by muse, mutect2, varscan2
- RTL8B | c.309G>A p.R103= | Silent (SNP) | VAF 74/85 reads (87%) | catalogued as rs1449700822, COSV66954333; called by muse, mutect2, varscan2
- TOE1 | c.309C>G p.A103= | Silent (SNP) | VAF 32/77 reads (42%) | catalogued as COSV59153450; called by muse, mutect2, varscan2
- TRPC7 | c.81G>A p.R27= | Silent (SNP) | VAF 102/211 reads (48%) | catalogued as COSV61459265; called by muse, mutect2, varscan2
- GBA3 | c.59-8129T>C | Intron (SNP) | VAF 10/208 reads (5%) | called by muse, mutect2
- TBC1D3F | c.*9C>T | 3'UTR (SNP) | VAF 211/901 reads (23%) | catalogued as rs371651652; called by muse, mutect2, varscan2
